Somatic mutation profile of tumor specimen MMRF_1783_1_BM_CD138pos (aliquot MMRF_1783_1_BM_CD138pos_T1_KBS5U_L05381) from MMRF case MMRF_1783, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.9 years (21,139 days).
Specimen MMRF_1783_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2b9157-93b6-4273-bba0-310e820c49ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1783_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1783_1_PB_Whole_C3_KBS5U_L05398; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28f90fcd-d488-437c-948a-8a67521a8afb

The open-access MAF lists 120 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 26, Silent 17, Intron 8, 5'UTR 5, 5'Flank 5, 3'Flank 4, Splice Site 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3075C>A p.N1025K | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1360363021; called by muse, mutect2, varscan2
- AKAP10 | c.1095C>G p.F365L | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.366); catalogued as COSV99855650; called by muse, mutect2
- AKAP13 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767973733; called by muse, mutect2, varscan2
- ALG9 | c.1760A>G p.Q587R (on ENST00000614444 / NM_001352418.1; = p.Q594R on NM_024740.2) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs782344967; called by muse, mutect2
- CEP350 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs755183539; called by muse, mutect2
- DOCK11 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); catalogued as rs1174860954, COSV52232844; called by muse, mutect2, varscan2
- GUCA2A | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572205991; called by muse, mutect2, varscan2
- H2AC6 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs987728493, COSV58414954; called by muse, mutect2, varscan2
- H3C8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs992932759, COSV59953008; called by muse, mutect2, varscan2
- HAPLN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs555462462, COSV57145600; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs370560636; called by muse, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, varscan2
- IGHV2-70 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs377422798; called by muse, varscan2
- IGHV2-70 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs759921720; called by muse, varscan2
- IGKV4-1 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs138603647; called by muse, mutect2, varscan2
- IGLC2 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs528109051; called by muse, mutect2, varscan2
- IGLV1-44 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.1); catalogued as rs180819320; called by muse, varscan2
- IGLV3-25 | c.159G>C p.W53C | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372042849; called by muse, varscan2
- IGLV5-45 | c.46+2T>C p.X16_splice | Splice Site (SNP) | VAF 53/94 reads (56%) | catalogued as rs763479033; called by muse, varscan2
- LIMK1 | c.1624A>T p.I542F | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60281670; called by muse, mutect2, varscan2
- LRRN3 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs762844497; called by muse, mutect2, varscan2
- LTB | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 184/360 reads (51%) | catalogued as rs538858213, COSV53000266; called by muse, varscan2
- MYO1D | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs545273791, COSV59022055; called by muse, mutect2, varscan2
- NATD1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.237); catalogued as rs373476359; called by muse, mutect2, varscan2
- NEO1 | c.3742+1G>A p.X1248_splice | Splice Site (SNP) | VAF 16/200 reads (8%) | catalogued as rs747725504, COSV99981617; called by muse, mutect2
- PBX4 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52060541; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as COSV52788468; called by muse, mutect2, varscan2
- RTP5 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs768854977, COSV58319270; called by muse, mutect2, varscan2
- THADA | c.2409A>C p.K803N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375611743; called by muse, mutect2, varscan2
- TMEM128 | c.165G>T p.W55C (on ENST00000382753 / NM_001297552.2; = p.W31C on NM_032927.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056319381; called by muse, mutect2, varscan2
- C3orf56 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by mutect2, varscan2
- C6orf58 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- COL12A1 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COL3A1 | c.860del p.N287Mfs*123 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- DCHS1 | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DOCK1 | c.5407C>A p.P1803T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GLRA3 | c.575-1G>T p.X192_splice | Splice Site (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- GRM1 | c.3560A>T p.Y1187F | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HEATR5B | c.4631T>G p.F1544C | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69D | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, varscan2
- IGHV2-70D | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IGHV2-70D | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- INTS5 | c.1216T>A p.L406M | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MOCS2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PRR32 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PZP | c.3745A>G p.N1249D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBNO2 | c.2594T>C p.F865S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX1 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, varscan2
- SOX15 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- THSD4 | c.2975T>C p.V992A | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USH2A | c.13443G>T p.R4481S | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.1111A>C p.I371L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2
- ZFYVE28 | c.1289G>C p.W430S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF768 | c.700A>T p.N234Y | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- DPP8 | c.76C>T p.L26= (on ENST00000341861 / NM_001320875.2; = p.L10= on NM_017743.6) | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as rs1230403833; called by muse, mutect2, varscan2
- EXO1 | c.2370A>G p.K790= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- FAM193A | c.375G>T p.A125= | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.273C>T p.S91= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs115694694; called by muse, varscan2
- IGLV5-45 | c.102A>G p.G34= | Silent (SNP) | VAF 91/212 reads (43%) | called by muse, varscan2
- IGLV5-45 | c.267A>G p.G89= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs375705788; called by muse, varscan2
- IKZF3 | c.1170C>T p.D390= | Silent (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- LTB | c.252C>T p.S84= | Silent (SNP) | VAF 115/225 reads (51%) | catalogued as rs4647186, COSV65815060; called by muse, mutect2, varscan2
- MYBPH | c.360G>A p.V120= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- NEK4 | c.2460A>G p.E820= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- NT5DC2 | c.622C>T p.L208= | Silent (SNP) | VAF 116/233 reads (50%) | called by muse, mutect2, varscan2
- POLE3 | c.348G>A p.S116= | Silent (SNP) | VAF 107/209 reads (51%) | catalogued as rs746011753; called by muse, mutect2, varscan2
- PTPRN2 | c.852C>A p.A284= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101233861; called by muse, mutect2
- PXMP4 | c.621G>A p.K207= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- RAB44 | c.2904G>A p.L968= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- RGS7 | c.183C>T p.D61= | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- SPTBN4 | c.3570G>A p.A1190= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs1213384597; called by muse, mutect2, varscan2
- ABLIM1 | chr10:114431759 C>T | 3'Flank (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- AF186192.2 | chr8:144698857 del CCTTCTTGCAAAGACAAGGCCACCCCTCCC | 5'Flank (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel
- ANKIB1 | c.*1491T>A | 3'UTR (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- APOLD1 | c.*812T>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021243 G>A | 5'Flank (SNP) | VAF 91/165 reads (55%) | called by muse, varscan2
- BCL7A | chr12:122021244 A>T | 5'Flank (SNP) | VAF 66/165 reads (40%) | called by muse, varscan2
- BCL7A | chr12:122021274 G>C | 5'Flank (SNP) | VAF 55/144 reads (38%) | catalogued as COSV55846384; called by muse, varscan2
- BCL7A | chr12:122021434 G>C | 5'Flank (SNP) | VAF 55/113 reads (49%) | called by muse, mutect2, varscan2
- BTBD3 | c.327-14G>T | Intron (SNP) | VAF 133/272 reads (49%) | called by muse, mutect2, varscan2
- CNGB1 | c.*184G>A | 3'UTR (SNP) | VAF 107/234 reads (46%) | catalogued as COSV51904198; called by muse, mutect2, varscan2
- DBNL | c.*6839G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- DCDC2 | c.*12A>G | 3'UTR (SNP) | VAF 75/203 reads (37%) | catalogued as rs758240952; called by muse, mutect2, varscan2
- EBF1 | c.-362T>C | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- EGR1 | c.-60C>T | 5'UTR (SNP) | VAF 19/39 reads (49%) | catalogued as rs1432434904; called by muse, mutect2, varscan2
- FAM160B2 | c.1851+136C>T | Intron (SNP) | VAF 27/36 reads (75%) | catalogued as rs191672801; called by muse, mutect2, varscan2
- FANCD2 | c.65-470C>T | Intron (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- FILIP1 | c.*171T>A | 3'UTR (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- GABRB3 | c.*1940C>A | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- GBX2 | c.-42C>T | 5'UTR (SNP) | VAF 10/22 reads (45%) | catalogued as rs991398264; called by muse, mutect2, varscan2
- GPR12 | c.-104G>A | 5'UTR (SNP) | VAF 40/63 reads (63%) | called by muse, mutect2, varscan2
- HEPH | chrX:66268744 G>A | 3'Flank (SNP) | VAF 8/53 reads (15%) | catalogued as rs928299809; called by muse, mutect2, varscan2
- LPCAT2 | c.*2363G>C | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- LTB | c.163-57G>A | Intron (SNP) | VAF 190/378 reads (50%) | catalogued as rs553997400; called by muse, varscan2
- LTB | c.163-141G>A | Intron (SNP) | VAF 112/229 reads (49%) | catalogued as rs4647180; called by muse, varscan2
- MSRB3 | c.*490G>A | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*942_*945del | 3'UTR (DEL) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- NT5E | c.*986G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222200892 A>G | 3'Flank (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4729C>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- PLPP3 | c.*134del | 3'UTR (DEL) | VAF 54/102 reads (53%) | catalogued as rs149661789; called by mutect2, varscan2
- POLRMT | c.823-50G>A | Intron (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- RGS21 | c.*814C>A | 3'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- RGS5 | c.*1990C>G | 3'UTR (SNP) | VAF 79/122 reads (65%) | called by muse, mutect2, varscan2
- SHQ1 | c.*788C>T | 3'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- SLC52A3 | c.1197+90G>A | Intron (SNP) | VAF 32/53 reads (60%) | catalogued as rs777023600; called by muse, mutect2, varscan2
- SOS1 | c.*2198A>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SPATA18 | c.*1239G>A | 3'UTR (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- STAT1 | c.*451T>A | 3'UTR (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- STEAP4 | c.*4854T>G | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- SYBU | c.*795C>T | 3'UTR (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- SYBU | c.*428T>G | 3'UTR (SNP) | VAF 75/148 reads (51%) | called by muse, mutect2, varscan2
- SYS1 | c.*1281C>G | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- SYT13 | c.*3138A>T | 3'UTR (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- TAP2 | c.*2657T>C | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10397041 G>A | 3'Flank (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- TNK2 | c.-18-6872C>T | Intron (SNP) | VAF 12/233 reads (5%) | catalogued as rs962746173; called by muse, mutect2
- ZNF57 | c.-59C>T | 5'UTR (SNP) | VAF 8/78 reads (10%) | catalogued as rs1194056934; called by muse, mutect2
- ZNF785 | c.*76G>T | 3'UTR (SNP) | VAF 105/321 reads (33%) | called by muse, mutect2, varscan2
